Somatic mutation profile of tumor specimen TCGA-KK-A8I8-01A (aliquot TCGA-KK-A8I8-01A-11D-A364-08) from TCGA case TCGA-KK-A8I8, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 69.9 years (25,546 days).
Specimen TCGA-KK-A8I8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab9cbcbd-9df8-485a-ab33-1e0ccd433a78.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A8I8-11A (Solid Tissue Normal), aliquot TCGA-KK-A8I8-11A-11D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b4f754a-425c-4ace-bb5a-46ba8a4a0dfd

The open-access MAF lists 22 somatic variants for this specimen: 14 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 6, Nonsense Mutation 2, 5'Flank 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GJB2 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as rs727503066, CM014710, COSV67010730; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AIFM3 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.469); catalogued as rs779484199, COSV59000635; called by muse, mutect2, varscan2
- ANKRD52 | c.1223A>G p.H408R | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV99921577; called by muse, mutect2, varscan2
- CDH23 | c.1656G>T p.L552F | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs753938557, COSV99823537; called by muse, varscan2
- HSP90AA1 | c.1994T>A p.L665* | Nonsense Mutation (SNP) | VAF 41/158 reads (26%) | catalogued as COSV99355503; called by muse, mutect2, varscan2
- ISLR | c.1042G>A p.G348S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.167); catalogued as rs773367130, COSV51433052; called by muse, mutect2, varscan2
- KRT85 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs766037993, COSV57738797; called by mutect2, varscan2
- NID2 | c.1787T>A p.L596* | Nonsense Mutation (SNP) | VAF 39/111 reads (35%) | catalogued as COSV99357173; called by muse, mutect2, varscan2
- PCDHA12 | c.2252C>T p.S751L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.426); catalogued as COSV99169600; called by muse, mutect2, varscan2
- POLR1A | c.4346G>A p.R1449Q | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs760185203, COSV99808345; called by muse, mutect2, varscan2
- PPFIA3 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV100495222; called by muse, mutect2
- TTC3 | c.3281G>A p.R1094H | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.869); catalogued as rs770766827, COSV61295999; called by muse, mutect2, varscan2
- MLLT6 | c.2031del p.A678Hfs*16 | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | called by mutect2, varscan2
- SPATA31A1 | c.1967C>A p.A656E | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.62); called by mutect2, varscan2
- AGPS | c.1737C>T p.F579= | Silent (SNP) | VAF 37/123 reads (30%) | catalogued as COSV99931678; called by muse, mutect2, varscan2
- FHDC1 | c.3060G>A p.P1020= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as rs986472114, COSV99471664; called by muse, mutect2
- PNPLA7 | c.1752C>T p.F584= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs367620575; called by muse, mutect2, varscan2
- SAMD9 | c.291A>G p.K97= | Silent (SNP) | VAF 73/247 reads (30%) | catalogued as rs1429968456, COSV101180359; called by muse, mutect2, varscan2
- TIGD3 | c.294G>A p.T98= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV99361917; called by muse, mutect2, varscan2
- ZNF883 | c.1096C>A p.R366= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs753867176, COSV71309042; called by muse, mutect2, varscan2
- RNU6-104P | chr8:43302043 G>A | 5'Flank (SNP) | VAF 51/239 reads (21%) | catalogued as rs770700319; called by muse, mutect2, varscan2
- RPL13A | c.342+79del | Intron (DEL) | VAF 22/67 reads (33%) | called by mutect2, pindel, varscan2
